Gene-level copy-number profile of tumor specimen TCGA-CN-6998-01A from TCGA case TCGA-CN-6998, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 53.2 years (19,447 days).
Specimen TCGA-CN-6998-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.a10ebaf5-a6f1-4db4-a59f-808e71577530.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-6998-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e0d746cd-7188-4174-aee1-8c2b3de069bf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,461; copy number 2: 49,649; copy number 3: 764; copy number 4: 2,363; copy number 5: 583.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-6998-01A-23D-2010-01): tumor purity 0.46, ploidy 4.85, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 583 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:70,109,782–73,915,010, 63 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:109,240,919–123,290,503, 135 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:124,462,485–145,066,685, 385 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,081. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
